Somatic mutation profile of tumor specimen 0DPSNK from CCDI case PBCDWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.0 years (351 days).
Specimen 0DPSNK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf6cc6e6-5e08-4325-9711-bbfaab084d10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPSN2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0755fadd-dc2d-43b9-a24e-9d976be2c4a5

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RELN | c.7769G>A p.R2590H | Missense Mutation (SNP) | VAF 280/1166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs541813551, COSV58996139; called by muse, varscan2
- LRRC59 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 174/508 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, varscan2
- PLA2G4C | c.1257+82C>T | Intron (SNP) | VAF 86/211 reads (41%) | catalogued as rs1469452322; called by muse, varscan2
